CCDI case PBCHVP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2ca6a5d5-ffc8-4764-8942-8c4345b985dc

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 2.2 years (812 days).

Biospecimens (3 samples)
- Sample 0DS9ZZ: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSA0B: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSA0U: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
